FM case AD2670 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Epithelial Neoplasms, NOS; Primary site: Esophagus.
https://portal.gdc.cancer.gov/cases/002630ec-b5c3-478a-a5e0-05f3d2f7eb12

Female, 52.8 years: Carcinoma, NOS (ICD-O-3 8010/3) of the esophagus; metastasis biopsied or resected from the liver. Tumor nuclei on the sequenced sample's slide: 50% (pathologist estimate recorded by GDC). Sample type: Metastatic.
